Somatic mutation profile of tumor specimen 0DF3K3 from CCDI case PBBRKB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 3.6 years (1,308 days).
Specimen 0DF3K3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 512b405f-66a4-49f6-8e79-91ce5ea0705a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF3K4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8347453-2abd-43e2-b0dc-7794c9f46c8a

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Intron 4, 3'UTR 4, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 229/504 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 237/813 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs397517154, CM070273, CM095735, CM116030, COSV67674782, COSV67675536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF5 | c.582C>G p.N194K | Missense Mutation (SNP) | VAF 73/1206 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV99282892; called by muse, mutect2
- ATP2A3 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770517233, COSV99989038; called by muse, mutect2, varscan2
- CACNA1G | c.6578C>T p.P2193L | Missense Mutation (SNP) | VAF 274/675 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs755509504, COSV100661974; called by muse, mutect2, varscan2
- CCDC88A | c.3353G>A p.S1118N | Missense Mutation (SNP) | VAF 24/658 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV55067892; called by muse, mutect2
- CDH19 | c.2031G>T p.E677D | Missense Mutation (SNP) | VAF 188/457 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1224027654, COSV100052290; called by muse, mutect2, varscan2
- DNAH11 | c.6167T>C p.L2056P | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898498100; called by muse, mutect2, varscan2
- GLB1L3 | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV66281666, COSV66282344; called by muse, mutect2, varscan2
- MMP17 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 130/376 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs749078612, COSV100861878; called by muse, mutect2, varscan2
- OR51E2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 105/375 reads (28%) | catalogued as COSV67808547; called by muse, mutect2, varscan2
- SHROOM4 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 123/150 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56783955; called by muse, mutect2, varscan2
- WEE2 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 158/701 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101285182; called by muse, mutect2, varscan2
- ARHGAP31 | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 235/809 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- DHX36 | c.2336A>G p.D779G | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DNAJC4 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 232/508 reads (46%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.952); called by muse, varscan2
- EIF2S3B | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 56/1482 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2
- FAM25G | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 54/487 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FAP | c.1379A>T p.K460M | Missense Mutation (SNP) | VAF 109/614 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- FBXO21 | c.1026C>A p.D342E | Missense Mutation (SNP) | VAF 120/356 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); called by mutect2, varscan2
- MAN2B2 | c.1540-1G>T p.X514_splice | Splice Site (SNP) | VAF 115/287 reads (40%) | called by muse, mutect2, varscan2
- PCDH15 | c.4828T>C p.S1610P (on ENST00000644397 / NM_001354429.2; = p.S1552P on NM_001142771.2) | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC4A4 | c.3099+2T>G p.X1033_splice (on ENST00000264485 / NM_001098484.3; = p.X989_splice on NM_003759.4) | Splice Site (SNP) | VAF 79/307 reads (26%) | called by muse, mutect2, varscan2
- SPEF2 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 106/635 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMTC2 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 196/549 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TTN | c.30056C>T p.P10019L (on ENST00000591111; = p.P9092L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/1137 reads (7%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- TTYH1 | c.493C>G p.R165G | Missense Mutation (SNP) | VAF 84/778 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- VPS13C | c.4972C>A p.H1658N (on ENST00000644861 / NM_020821.3; = p.H1615N on NM_017684.5) | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZYX | c.1335C>A p.N445K | Missense Mutation (SNP) | VAF 179/497 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FGF13 | c.213G>A p.P71= | Silent (SNP) | VAF 143/170 reads (84%) | catalogued as rs1189564654; called by muse, mutect2, varscan2
- GLYAT | c.96C>A p.V32= | Silent (SNP) | VAF 20/479 reads (4%) | catalogued as COSV99557257; called by muse, mutect2
- LYPLA2 | c.39T>C p.D13= | Silent (SNP) | VAF 31/479 reads (6%) | called by muse, mutect2
- NIBAN1 | c.2133G>A p.A711= | Silent (SNP) | VAF 151/375 reads (40%) | catalogued as rs766138222, COSV100836416, COSV62284518; called by muse, mutect2, varscan2
- SOBP | c.945G>T p.V315= | Silent (SNP) | VAF 110/344 reads (32%) | called by muse, mutect2, varscan2
- SP7 | c.255C>A p.T85= | Silent (SNP) | VAF 218/491 reads (44%) | called by muse, mutect2, varscan2
- ZNF695 | c.546A>G p.K182= | Silent (SNP) | VAF 244/648 reads (38%) | catalogued as rs933342551; called by muse, mutect2, varscan2
- ZNF862 | c.258C>T p.G86= | Silent (SNP) | VAF 46/652 reads (7%) | called by muse, mutect2
- CNP | c.*3457C>T | 3'UTR (SNP) | VAF 50/96 reads (52%) | catalogued as rs1321829993, COSV57270765; called by muse, mutect2, varscan2
- DNAH1 | c.10824-82C>A | Intron (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- FANCI | c.*59C>A | 3'UTR (SNP) | VAF 48/132 reads (36%) | called by muse, mutect2, varscan2
- FOXD4 | c.*31C>A | 3'UTR (SNP) | VAF 97/328 reads (30%) | called by muse, mutect2
- RELT | c.1047-34G>A | Intron (SNP) | VAF 59/134 reads (44%) | catalogued as rs751430619, COSV50361226; called by muse, mutect2, varscan2
- SERPINF1 | c.*71C>A | 3'UTR (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- USP28 | c.57+802C>A | Intron (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- ZNF517 | c.34-59C>A | Intron (SNP) | VAF 181/354 reads (51%) | called by muse, mutect2, varscan2
